Somatic mutation profile of tumor specimen TCGA-EM-A2CQ-01A (aliquot TCGA-EM-A2CQ-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 40.5 years (14,776 days).
Specimen TCGA-EM-A2CQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 699517d7-0d9a-4c4d-9593-e55f3411b040.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CQ-10A (Blood Derived Normal), aliquot TCGA-EM-A2CQ-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c36ff12c-6c5f-457f-aa90-a0e12477ecf3

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ELF4 | c.1694C>A p.T565N | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.63); catalogued as rs1239010127, COSV57455553; called by muse, mutect2, varscan2
- IGHV6-1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1434348475; called by muse, mutect2, varscan2
- MGAM | c.3797T>C p.M1266T | Missense Mutation (SNP) | VAF 94/324 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV72076059; called by muse, mutect2, varscan2
- NPC1L1 | c.1382C>A p.A461E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56931051; called by muse, mutect2, varscan2
- TNXB | c.6009C>T p.D2003= (on ENST00000647633; = p.D1756= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs377387902, COSV64489739; called by muse, mutect2, varscan2
- TRNT1 | c.1096C>T p.L366= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV51643019; called by muse, mutect2, varscan2
